Somatic mutation profile of tumor specimen TCGA-92-7340-01A (aliquot TCGA-92-7340-01A-21D-2042-08) from TCGA case TCGA-92-7340, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.0 years (16,447 days).
Specimen TCGA-92-7340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32e51438-9ee0-4044-94e3-5b7eb61a6ec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-7340-10A (Blood Derived Normal), aliquot TCGA-92-7340-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e11ab33-cd02-4bf1-a138-3f8839dd3f3b

The open-access MAF lists 464 somatic variants for this specimen: 342 protein-altering or splice-affecting, 113 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 304, Silent 113, Nonsense Mutation 20, Frame Shift Del 6, Splice Region 6, Splice Site 4, RNA 3, Intron 3, Frame Shift Ins 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 5/90 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1057519934, COSV55876538, COSV55894288; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA12 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.629); catalogued as rs567588953, COSV55960138, COSV99789346; called by muse, mutect2, varscan2
- ABCA6 | c.4579A>T p.I1527F | Missense Mutation (SNP) | VAF 67/351 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99446214; called by muse, mutect2, varscan2
- ABCE1 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99668503; called by muse, mutect2, varscan2
- ACTC1 | c.130-1G>C p.X44_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99291754; called by muse, mutect2, varscan2
- ADGRB3 | c.3486G>C p.L1162F | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53234959, COSV99484492; called by muse, mutect2, varscan2
- ADGRL1 | c.2959C>T p.R987C (on ENST00000340736 / NM_001008701.3; = p.R982C on NM_014921.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1329892867, COSV100529345; called by mutect2, varscan2
- AFF3 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs781704362, COSV57839916; called by muse, mutect2, varscan2
- AKAP9 | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV100662221; called by muse, mutect2, varscan2
- ALG13 | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99321944; called by muse, mutect2, varscan2
- ALPI | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV99785810; called by muse, mutect2, varscan2
- AMER1 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748618414, COSV100365809; called by muse, mutect2, varscan2
- ANAPC2 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100118982; called by muse, mutect2, varscan2
- ANKFN1 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100593329; called by muse, mutect2, varscan2
- ANXA13 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 60/316 reads (19%) | catalogued as rs766941266, COSV51627094; called by muse, mutect2, varscan2
- AOC2 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99513579; called by muse, mutect2, varscan2
- APBB1IP | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV100882007; called by muse, mutect2
- APC2 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99279329; called by muse, mutect2, varscan2
- APOBEC3B | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100213718; called by muse, mutect2, varscan2
- AR | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV65964072, COSV65965216; called by muse, mutect2, varscan2
- ARFGEF1 | c.4990G>A p.D1664N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99141796; called by muse, mutect2, varscan2
- ARGFX | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV100544101; called by muse, mutect2, varscan2
- ARHGAP29 | c.3630C>G p.D1210E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780996785, COSV99557948; called by muse, mutect2, varscan2
- ARR3 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367462161, COSV100330848; called by muse, mutect2
- ASB4 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99987132; called by muse, mutect2, varscan2
- ASCC2 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 51/439 reads (12%) | catalogued as COSV100316172, COSV100316331; called by muse, mutect2, varscan2
- ASPHD2 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs1250165420, COSV99313254; called by muse, mutect2, varscan2
- ASTN1 | c.1972G>C p.G658R | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99921071; called by muse, mutect2, varscan2
- ATL1 | c.987C>G p.F329L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100612994; called by muse, mutect2, varscan2
- ATMIN | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV100214572; called by muse, mutect2, varscan2
- ATP10A | c.3789G>T p.W1263C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100791064, COSV63520914; called by muse, mutect2, varscan2
- ATP1B1 | c.97+1G>T p.X33_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as rs879113954, COSV100891619; called by muse, mutect2, varscan2
- ATP2C1 | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371236506; called by muse, mutect2, varscan2
- BAHCC1 | c.2935G>T p.G979C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57029077; called by muse, mutect2, varscan2
- BRINP2 | c.1807A>T p.M603L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100837978; called by muse, mutect2, varscan2
- C10orf90 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52958706; called by muse, mutect2, varscan2
- C5 | c.4240G>T p.E1414* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56326132, COSV99797588; called by muse, mutect2
- C6 | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs754488543, COSV99666867; called by muse, mutect2
- C8orf37 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs768222931, COSV99713106; called by muse, mutect2, varscan2
- CA10 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562395; called by muse, mutect2, varscan2
- CCBE1 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101232806; called by muse, mutect2, varscan2
- CCDC127 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99722937; called by muse, mutect2, varscan2
- CCDC171 | c.2515G>A p.V839M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99900263; called by muse, mutect2, varscan2
- CCDC87 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149088581; called by muse, mutect2
- CCDC92 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99435417; called by muse, varscan2
- CCDC92 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99435420; called by muse, varscan2
- CDH18 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 49/164 reads (30%) | catalogued as COSV99933587; called by muse, mutect2, varscan2
- CDH9 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50375363, COSV99142888; called by muse, mutect2, varscan2
- CDYL | c.808C>G p.P270A (on ENST00000328908 / NM_001368125.1; = p.P216A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV100189098; called by muse, mutect2, varscan2
- CEP104 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV100986602; called by muse, mutect2, varscan2
- CFAP69 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100289982; called by muse, mutect2, varscan2
- CHRD | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV99200330; called by muse, mutect2, varscan2
- CHRDL2 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1193510812, COSV99733677; called by muse, mutect2, varscan2
- CLEC4F | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV99713672, COSV99713850; called by muse, mutect2, varscan2
- COL13A1 | c.1643G>T p.G548V (on ENST00000398978 / NM_001130103.2; = p.G491V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100637401; called by muse, mutect2, varscan2
- COL1A1 | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV99866877; called by muse, mutect2, varscan2
- COL26A1 | c.173A>T p.H58L | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV100561631; called by muse, mutect2, varscan2
- COL5A3 | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99318519; called by muse, mutect2
- CP | c.2291C>G p.S764* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99223961; called by muse, mutect2
- CR1L | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as COSV99687069; called by muse, mutect2, varscan2
- CRYBA1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV99836984; called by muse, mutect2, varscan2
- CSMD2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as COSV53887331, COSV99588413; called by muse, mutect2
- CSMD3 | c.10331T>C p.L3444S (on ENST00000297405 / NM_001363185.1; = p.L3275S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830633; called by muse, mutect2, varscan2
- CSMD3 | c.2015A>T p.Y672F (on ENST00000297405 / NM_001363185.1; = p.Y568F on NM_052900.3) | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); catalogued as COSV99830637; called by muse, mutect2, varscan2
- DGKI | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933422; called by muse, mutect2, varscan2
- DLG3 | c.2121G>C p.Q707H (on ENST00000374360 / NM_021120.4; = p.Q402H on NM_020730.3) | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99529386; called by muse, mutect2, varscan2
- DMBT1 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963526763, COSV100352650, COSV100352669; called by muse, mutect2, varscan2
- DMWD | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs765984271, COSV99352979; called by muse, mutect2, varscan2
- DNAH11 | c.10825G>A p.E3609K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100178505; called by muse, mutect2, varscan2
- DNAH5 | c.2177A>G p.Q726R | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99447903; called by muse, mutect2, varscan2
- DNHD1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772664290, COSV54437392; called by muse, mutect2, varscan2
- DPF3 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.575); catalogued as COSV100818487; called by muse, mutect2, varscan2
- DST | c.18760G>T p.E6254* (on ENST00000361203 / NM_001374722.1; = p.E3951* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99753947; called by muse, varscan2
- DSTYK | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100904514; called by muse, mutect2, varscan2
- DTNA | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV99311987; called by muse, mutect2, varscan2
- EFL1 | c.1839A>T p.E613D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV99186652; called by muse, mutect2, varscan2
- EID2 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as rs1331701171, COSV101180481; called by muse, mutect2
- EIF2AK3 | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751877330, COSV100303616; called by muse, mutect2, varscan2
- ERCC6L | c.2349G>T p.E783D | Missense Mutation (SNP) | VAF 140/237 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100559068; called by muse, mutect2, varscan2
- EXOC3L4 | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV101197588, COSV101197741; called by muse, mutect2
- EXOC7 | c.1725C>G p.I575M (on ENST00000335146 / NM_001145297.4; = p.I493M on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100135083; called by muse, mutect2, varscan2
- FAM71C | c.25T>C p.Y9H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV100175714; called by muse, mutect2
- FAT4 | c.8614C>G p.P2872A | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58703955; called by muse, mutect2
- FAXC | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1462621981, COSV101067109; called by muse, mutect2, varscan2
- FLG | c.5480C>A p.S1827Y | Missense Mutation (SNP) | VAF 79/846 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1361375721, COSV100911399; called by muse, mutect2
- FRMPD4 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV101042593, COSV66217632; called by muse, mutect2, varscan2
- GALM | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55371690, COSV99697117; called by muse, mutect2, varscan2
- GALNTL5 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755106841, COSV101217753; called by muse, mutect2, varscan2
- GDF5 | c.947G>A p.W316* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV65499466; called by muse, varscan2
- GET4 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs758012231, COSV99762934; called by muse, mutect2, varscan2
- GNL3L | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100328261; called by muse, mutect2
- GPR182 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs753318249, COSV100267679; called by muse, mutect2, varscan2
- GRIA4 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as COSV56911735; called by muse, mutect2, varscan2
- GRIP1 | c.2945T>G p.V982G (on ENST00000359742 / NM_001379345.1; = p.V930G on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV99668947; called by muse, mutect2, varscan2
- GRIP1 | c.1724A>T p.K575M (on ENST00000359742 / NM_001379345.1; = p.K523M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99668951; called by muse, mutect2, varscan2
- GSTA3 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99274490; called by muse, mutect2, varscan2
- HCN1 | c.2285C>A p.T762K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.081); catalogued as COSV100299634, COSV57491554; called by muse, mutect2, varscan2
- HDLBP | c.2184C>A p.F728L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV100190289; called by muse, varscan2
- HECW1 | c.2098G>T p.A700S | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs368768711; called by muse, mutect2, varscan2
- HEXA | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99173706; called by muse, mutect2, varscan2
- HEY2 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100856350, COSV64240483; called by muse, mutect2
- HFM1 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99645799; called by muse, mutect2
- HIVEP2 | c.6272G>A p.R2091K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.952); catalogued as COSV99172372; called by muse, mutect2, varscan2
- HLA-B | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101317993; called by muse, mutect2
- HMX2 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as COSV100378722; called by muse, mutect2
- HS3ST3A1 | c.1142G>C p.R381P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV52375380; called by muse, mutect2
- HS6ST3 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100940321, COSV65002569; called by muse, mutect2, varscan2
- IDI2 | c.22T>A p.W8R | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99479169; called by muse, mutect2, varscan2
- IFT122 | c.1114G>T p.V372F (on ENST00000348417 / NM_052989.3; = p.V313F on NM_018262.4) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99959077; called by muse, mutect2, varscan2
- IGSF9 | c.1862C>T p.P621L (on ENST00000368094 / NM_001135050.2; = p.P605L on NM_020789.4) | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs546681175, COSV63639444; called by muse, mutect2, varscan2
- IL13RA1 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100861707; called by muse, mutect2, varscan2
- IMPA1 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313019644, COSV56273587, COSV99808887; called by muse, mutect2, varscan2
- INSR | c.3722C>G p.S1241C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57168748; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1106G>A p.R369Q (on ENST00000485419 / NM_001197113.1; = p.R293Q on NM_014575.3) | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767522191, COSV61838173; called by muse, mutect2, varscan2
- ITGA11 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59881181; called by muse, mutect2, varscan2
- KAT7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52013705; called by muse, mutect2, varscan2
- KCNH7 | c.3162G>T p.Q1054H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1287295418, COSV100147412, COSV59788657; called by muse, mutect2, varscan2
- KCNH8 | c.2665A>G p.R889G | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1360880137, COSV100111275; called by muse, mutect2
- KCNT2 | c.2825G>A p.R942K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99652754; called by muse, mutect2, varscan2
- KEAP1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV50260706, COSV99407609; called by muse, mutect2, varscan2
- KHDRBS2 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV55468078, COSV99832645; called by muse, mutect2
- KHSRP | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231171; called by muse, mutect2, varscan2
- KIAA0319 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.165); catalogued as COSV65500783; called by muse, mutect2, varscan2
- KIF21B | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1200416395, COSV59758331; called by mutect2, varscan2
- KIF26A | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1489038183, COSV100181014; called by muse, mutect2, varscan2
- KL | c.1599A>T p.Q533H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV101199068; called by muse, mutect2, varscan2
- KLHL23 | c.1609T>C p.W537R | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775663; called by muse, mutect2, varscan2
- KRT33B | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs553797257, COSV99290550; called by muse, mutect2, varscan2
- LAMB2 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV100565118; called by muse, mutect2
- LDAH | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99425505; called by muse, mutect2, varscan2
- LIN7B | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as COSV99674426; called by muse, mutect2, varscan2
- LRP1B | c.6119C>A p.A2040E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV101255037; called by muse, mutect2, varscan2
- LRP1B | c.5444G>C p.R1815P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101255038, COSV67205800; called by muse, mutect2, varscan2
- LRRC40 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs757402855, COSV100918736; called by muse, mutect2, varscan2
- LRRC66 | c.2591C>G p.S864* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100602910; called by muse, mutect2, varscan2
- LRRC7 | c.964G>C p.D322H (on ENST00000651989 / NM_001370785.2; = p.D289H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50496995, COSV50601277; called by muse, mutect2, varscan2
- LRRTM3 | c.1666A>T p.T556S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as COSV100791577; called by muse, mutect2, varscan2
- LTBP2 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100000066; called by muse, mutect2
- MAGOH | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV101012339; called by muse, mutect2
- MAP3K15 | c.1437C>A p.V479= | Splice Region (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100134510; called by muse, mutect2, varscan2
- MAPKAP1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as COSV99784655; called by muse, mutect2, varscan2
- MAST1 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99262674; called by muse, mutect2
- MCF2 | c.1365G>C p.G455= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100644665; called by muse, mutect2, varscan2
- MEF2B | c.676-1G>C p.X226_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99364535; called by muse, mutect2, varscan2
- MEN1 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99580691; called by muse, mutect2, varscan2
- MGAT2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs372538664; called by muse, mutect2, varscan2
- MGME1 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100891345; called by muse, mutect2, varscan2
- MKI67 | c.9743G>C p.R3248T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100896389; called by muse, mutect2, varscan2
- MLLT3 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100580864; called by muse, mutect2
- MMAA | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99849744; called by muse, mutect2, varscan2
- MME | c.973A>T p.N325Y | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100852346; called by muse, mutect2, varscan2
- MMP20 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199788797, COSV99497577; called by muse, mutect2, varscan2
- MMRN2 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100922546; called by muse, mutect2, varscan2
- MTHFD2 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs374942985; called by muse, mutect2
- MUC16 | c.35516C>T p.A11839V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.013); catalogued as rs777142957, COSV101199315; called by muse, mutect2, varscan2
- MUC16 | c.21458C>T p.P7153L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs1289597761, COSV101199316; called by muse, mutect2, varscan2
- MUC7 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100512246; called by muse, mutect2, varscan2
- MYH1 | c.1146A>T p.E382D | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99875481; called by muse, mutect2, varscan2
- MYH15 | c.2199G>T p.R733S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842879; called by muse, mutect2, varscan2
- MYH2 | c.4166C>G p.T1389R | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99819800; called by muse, mutect2, varscan2
- MYH3 | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 18/206 reads (9%) | catalogued as COSV99878027; called by muse, mutect2
- MYO18A | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100572114; called by muse, mutect2, varscan2
- NCOR2 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1333540307, COSV100657137; called by muse, mutect2, varscan2
- NDC1 | c.766A>T p.R256W | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99323477; called by muse, mutect2, varscan2
- NDST3 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99630129; called by muse, mutect2, varscan2
- NELL2 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1379064978, COSV100419265; called by muse, mutect2, varscan2
- NLRP4 | c.2701G>T p.E901* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100016027, COSV56707914; called by muse, mutect2, varscan2
- NLRP5 | c.2201G>T p.R734L | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101173528, COSV66762506, COSV66765656; called by muse, mutect2, varscan2
- NME8 | c.569C>G p.T190R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149877831; called by muse, mutect2
- NPAP1 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.668); catalogued as rs761309766, COSV61504000, COSV61505225; called by muse, mutect2, varscan2
- NPR2 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100709425; called by muse, mutect2, varscan2
- NSUN3 | c.129A>G p.I43M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100113199; called by muse, mutect2
- NTN5 | c.1026C>T p.D342= | Splice Region (SNP) | VAF 18/160 reads (11%) | catalogued as COSV99539355; called by muse, mutect2, varscan2
- NUP93 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV100360104; called by muse, mutect2
- NWD1 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV100342297, COSV60340766; called by muse, mutect2, varscan2
- NYAP2 | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV56005652, COSV56016052, COSV99796255; called by muse, mutect2, varscan2
- OBSCN | c.20366C>T p.S6789F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs755643834, COSV100802984; called by muse, mutect2, varscan2
- OLFM3 | c.1173G>C p.K391N (on ENST00000338858 / NM_001288821.1; = p.K371N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100129195; called by muse, mutect2, varscan2
- OR10AG1 | c.106A>T p.I36L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs1328227884, COSV56632248; called by muse, mutect2, varscan2
- OR10T2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100554912; called by muse, mutect2, varscan2
- OR12D2 | c.-1G>A | Splice Region (SNP) | VAF 49/218 reads (22%) | catalogued as COSV101011196; called by muse, mutect2, varscan2
- OR14I1 | c.447C>A p.S149R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100700461; called by muse, mutect2, varscan2
- OR2B3 | c.364A>T p.R122* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV101013772; called by muse, mutect2, varscan2
- OR2T1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs1244611327, COSV100822285; called by muse, mutect2, varscan2
- OR4C46 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as COSV100060581; called by muse, mutect2, varscan2
- OR4D2 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101613849; called by muse, mutect2, varscan2
- OR51M1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1204694306, COSV60784013, COSV60784470; called by muse, mutect2, varscan2
- OR52E6 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100259257; called by muse, mutect2, varscan2
- OR5H15 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100736645; called by muse, mutect2, varscan2
- OR5M1 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs772373306, COSV101591549, COSV73201989; called by muse, mutect2, varscan2
- OR6F1 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100129084; called by muse, mutect2, varscan2
- P3H3 | c.1541C>G p.T514R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99301088; called by muse, mutect2, varscan2
- PABPC5 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs977990721, COSV100442254; called by muse, mutect2, varscan2
- PANX1 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs577336224, COSV99921744; called by muse, mutect2, varscan2
- PARP9 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs751697051, COSV100831059; called by muse, mutect2, varscan2
- PATZ1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.421); catalogued as rs1460875506, COSV99315261; called by muse, mutect2, varscan2
- PCDHA4 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100793299; called by muse, mutect2, varscan2
- PCDHA5 | c.1214C>G p.S405W | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100972210; called by muse, mutect2, varscan2
- PCDHA7 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.039); catalogued as COSV100971366; called by muse, mutect2, varscan2
- PCDHB3 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50574236, COSV99166875; called by muse, mutect2, varscan2
- PCF11 | c.2708G>C p.R903T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100018103; called by muse, mutect2, varscan2
- PDE1C | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV100371999; called by muse, mutect2, varscan2
- PDE1C | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.717); catalogued as COSV101275457, COSV68819282; called by muse, mutect2
- PDZD2 | c.4015G>T p.V1339F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs759372157, COSV56864889, COSV99224543; called by muse, mutect2, varscan2
- PEG3 | c.3709A>T p.S1237C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99688318; called by muse, mutect2, varscan2
- PEG3 | c.1984T>A p.C662S | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); catalogued as COSV55645754, COSV99688320; called by muse, mutect2, varscan2
- PHC3 | c.1819G>C p.D607H (on ENST00000494943 / NM_001308116.2; = p.D619H on NM_024947.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV101520150; called by muse, mutect2, varscan2
- PIK3CB | c.2635G>C p.D879H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100005442; called by muse, mutect2
- PKHD1 | c.9591G>C p.Q3197H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs1421251307, COSV100582391; called by muse, mutect2, varscan2
- PLCL2 | c.1478A>G p.Q493R (on ENST00000615277 / NM_001144382.2; = p.Q367R on NM_015184.5) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV101196645; called by muse, mutect2, varscan2
- PLSCR1 | c.296T>C p.L99S | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678344; called by muse, mutect2, varscan2
- PLXNA2 | c.3505C>A p.L1169I | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV100885311; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100982442; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1642T>C p.Y548H | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1363112595, COSV99461127; called by muse, mutect2, varscan2
- PPAT | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs756567329, COSV99947170; called by muse, mutect2, varscan2
- PPP1CA | c.923A>T p.Q308L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100334923; called by muse, mutect2, varscan2
- PRKACB | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1309386302, COSV100853909; called by muse, mutect2, varscan2
- PROX1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as COSV99799057; called by muse, mutect2, varscan2
- PRR30 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV99574419; called by muse, mutect2, varscan2
- PRRC2A | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100784550; called by muse, mutect2, varscan2
- PSG3 | c.711G>A p.P237= | Splice Region (SNP) | VAF 34/354 reads (10%) | catalogued as rs2353157, COSV59505528; called by muse, varscan2
- PSG3 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100548840; called by muse, mutect2, varscan2
- PSKH1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs768583092, COSV99344578; called by muse, mutect2, varscan2
- PTF1A | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV100919578; called by muse, mutect2
- PTGDR2 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.379); catalogued as COSV99920110; called by muse, varscan2
- PTPRO | c.2770G>C p.D924H (on ENST00000281171 / NM_030667.3; = p.D896H on NM_002848.4) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99840231; called by muse, mutect2, varscan2
- RAD17 | c.490C>A p.P164T (on ENST00000380774 / NM_133339.2; = p.P153T on NM_002873.1) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99281342; called by muse, mutect2
- RBMS2 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV100008457, COSV56266017; called by muse, mutect2, varscan2
- REL | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.395); catalogued as COSV99691990; called by muse, mutect2, varscan2
- RGS22 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1221418331, COSV100693141, COSV100693878; called by muse, mutect2, varscan2
- ROBO1 | c.3322G>T p.E1108* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV71399989; called by muse, mutect2
- RPGRIP1 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52851774; called by muse, mutect2
- RUBCN | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs550326951, COSV99583729; called by muse, mutect2, varscan2
- RUSC1 | c.2248C>G p.L750V (on ENST00000368352 / NM_001105203.2; = p.L281V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as COSV99429659; called by muse, mutect2, varscan2
- RYR1 | c.4331C>A p.P1444H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615353; called by muse, mutect2, varscan2
- RYR2 | c.4348T>A p.F1450I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100769324; called by muse, mutect2, varscan2
- SAFB2 | c.2296C>A p.H766N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99385586; called by muse, mutect2, varscan2
- SALL4 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99409386; called by muse, mutect2, varscan2
- SCGB2A1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV99793720; called by muse, mutect2, varscan2
- SEPTIN10 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61779959; called by muse, mutect2, varscan2
- SETBP1 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV56341232; called by muse, mutect2, varscan2
- SLC14A2 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99675328; called by muse, mutect2, varscan2
- SLC17A6 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV54141358, COSV99581204; called by muse, mutect2, varscan2
- SLC22A7 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV101000804, COSV101000862; called by muse, mutect2, varscan2
- SLC27A3 | c.351G>C p.W117C | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV99669873; called by muse, mutect2, varscan2
- SLC2A3 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs201737691, COSV50002302, COSV50003055; called by muse, mutect2, varscan2
- SLC35G1 | c.456G>C p.Q152H (on ENST00000427197 / NM_001134658.3; = p.Q151H on NM_153226.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV101004045; called by muse, mutect2, varscan2
- SLC38A6 | c.115A>T p.R39* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99712050; called by muse, mutect2, varscan2
- SLC46A3 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99906211; called by muse, mutect2, varscan2
- SLC4A9 | c.1920C>A p.F640L (on ENST00000507527 / NM_001258428.2; = p.F616L on NM_031467.3) | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99138636; called by muse, mutect2, varscan2
- SLC5A7 | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99886521; called by muse, mutect2, varscan2
- SLC6A16 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1368765660, COSV100242664; called by muse, mutect2, varscan2
- SLC7A3 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53228660; called by muse, mutect2, varscan2
- SLC9B2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100293969; called by muse, mutect2, varscan2
- SMARCB1 | c.96G>A p.V32= | Splice Region (SNP) | VAF 57/231 reads (25%) | catalogued as COSV99575134; called by muse, mutect2, varscan2
- SMG5 | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV100700758; called by muse, mutect2, varscan2
- SNAP47 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100248044; called by muse, mutect2, varscan2
- SNRNP48 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.58); catalogued as COSV100672934; called by muse, mutect2
- SORCS1 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.071); catalogued as COSV99545071; called by muse, mutect2, varscan2
- SPATA17 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs540164939, COSV65122087; called by muse, mutect2, varscan2
- STARD6 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1257511221, COSV100323399; called by muse, mutect2, varscan2
- STEAP1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs758880644, COSV99787596; called by muse, mutect2
- STON1 | c.2185A>G p.I729V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1370891963, COSV100561698; called by muse, mutect2
- SYNE1 | c.25548G>C p.E8516D (on ENST00000367255 / NM_182961.4; = p.E8468D on NM_033071.3) | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV99559305; called by muse, mutect2
- SYNE1 | c.21814A>G p.K7272E (on ENST00000367255 / NM_182961.4; = p.K7201E on NM_033071.3) | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99559310; called by muse, mutect2, varscan2
- SYNE1 | c.10700C>G p.A3567G (on ENST00000367255 / NM_182961.4; = p.A3574G on NM_033071.3) | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99559317; called by muse, mutect2, varscan2
- SYNE2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100420118; called by muse, mutect2, varscan2
- SYNE2 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100420120; called by mutect2, varscan2
- SZT2 | c.6262C>T p.R2088* (on ENST00000634258 / NM_001365999.1; = p.R2031* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 7/106 reads (7%) | catalogued as COSV100987051; called by muse, mutect2
- TANC1 | c.2396C>A p.S799Y | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99713538, COSV99715071; called by muse, mutect2, varscan2
- TAS2R31 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV101114578; called by muse, mutect2
- TBX19 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014745, COSV100892342; called by muse, mutect2, varscan2
- TBX22 | c.249C>G p.S83R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV100960718; called by muse, mutect2, varscan2
- TDRD5 | c.764T>A p.M255K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99675919; called by muse, mutect2, varscan2
- TFEB | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs745674792, COSV100026106; called by muse, mutect2, varscan2
- TGIF2LX | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99383266; called by muse, mutect2, varscan2
- TLE6 | c.1468A>G p.S490G (on ENST00000246112 / NM_001143986.2; = p.S367G on NM_024760.3) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.795); catalogued as rs1317512322, COSV99504186; called by muse, mutect2
- TM4SF1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 53/325 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs746963430, COSV59525444, COSV59525888; called by muse, mutect2, varscan2
- TM4SF1 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100542971; called by muse, mutect2
- TMEM89 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140040188; called by muse, mutect2, varscan2
- TMPRSS11A | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100602621; called by muse, mutect2
- TMX3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100218303; called by muse, mutect2
- TNKS | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.941); catalogued as COSV100126633; called by muse, mutect2, varscan2
- TP53 | c.132del p.M44Ifs*79 | Frame Shift Del (DEL) | VAF 100/304 reads (33%) | catalogued as COSV53759087; called by mutect2, pindel, varscan2
- TP53BP2 | c.1382G>T p.R461L (on ENST00000343537 / NM_001031685.3; = p.R332L on NM_005426.2) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV100636563, COSV59066991; called by muse, mutect2, varscan2
- TRA2B | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764180360, COSV99373232; called by muse, mutect2
- TRIM32 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1215135171; called by muse, varscan2
- TRIM42 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV99648222, COSV99648902; called by muse, mutect2
- TRIML1 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100205873; called by muse, mutect2
- TRPS1 | c.2530G>T p.G844C (on ENST00000220888 / NM_001330599.2; = p.G857C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV99629731; called by muse, mutect2
- TRPV6 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV100844234; called by muse, mutect2
- TTN | c.79781C>A p.A26594D (on ENST00000591111; = p.A19170D on NM_003319.4) | Missense Mutation (SNP) | VAF 29/191 reads (15%) | PolyPhen probably damaging (0.925); catalogued as rs1176082000, COSV100604309; called by muse, mutect2, varscan2
- TTN | c.41975G>T p.G13992V (on ENST00000591111; = p.G6568V on NM_003319.4) | Missense Mutation (SNP) | VAF 26/153 reads (17%) | PolyPhen probably damaging (1); catalogued as COSV100604312, COSV60224458; called by muse, mutect2, varscan2
- TTN | c.36479G>A p.S12160N (on ENST00000591111; = p.S4736N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | PolyPhen benign (0); catalogued as rs757590541, COSV100604315; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.31704G>T p.M10568I (on ENST00000591111; = p.M9641I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | PolyPhen benign (0.003); catalogued as COSV60372820; called by muse, mutect2
- TUBGCP4 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as COSV99538948; called by muse, mutect2
- TWNK | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs753457416, COSV99272240; called by muse, mutect2, varscan2
- UBE3A | c.820C>G p.H274D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99217016; called by muse, mutect2, varscan2
- UBQLN3 | c.1790A>C p.H597P | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100293528; called by muse, mutect2, varscan2
- UBR3 | c.5539C>T p.R1847W | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99773783; called by muse, mutect2
- USH2A | c.13380A>G p.I4460M | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1244395010, COSV100232571; called by muse, mutect2, varscan2
- VAV1 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100408879; called by muse, mutect2, varscan2
- VCAM1 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV99658389; called by muse, mutect2, varscan2
- VCL | c.1053G>C p.Q351H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99280661; called by muse, mutect2
- VPS13C | c.10444A>G p.T3482A (on ENST00000644861 / NM_020821.3; = p.T3439A on NM_017684.5) | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs780965164, COSV99827988; called by muse, mutect2
- WAPL | c.3531G>T p.Q1177H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV99556401; called by muse, mutect2
- WASHC5 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV59193995, COSV59194172; called by muse, mutect2, varscan2
- XPNPEP1 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.501); catalogued as rs953223721, COSV100450932; called by muse, mutect2
- XPNPEP3 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100846673; called by muse, mutect2, varscan2
- ZIC1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs748870052, COSV99291768; called by muse, mutect2, varscan2
- ZNF12 | c.991G>T p.G331W (on ENST00000405858 / NM_016265.4; = p.G293W on NM_006956.3) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703646; called by muse, mutect2, varscan2
- ZNF182 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100526993, COSV59357666; called by muse, mutect2, varscan2
- ZNF184 | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.632); catalogued as COSV99279530; called by muse, mutect2
- ZNF197 | c.1543T>C p.C515R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482037; called by muse, mutect2, varscan2
- ZNF248 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV61997240; called by muse, mutect2, varscan2
- ZNF257 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555293490, COSV71310222, COSV71312175, COSV71312346; called by muse, mutect2, varscan2
- ZNF296 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs113643466; called by muse, mutect2, varscan2
- ZNF329 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as COSV100798710; called by muse, mutect2, varscan2
- ZNF423 | c.2506G>A p.E836K (on ENST00000563137 / NM_001379286.1; = p.E828K on NM_015069.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.437); catalogued as COSV52203657; called by muse, mutect2, varscan2
- ZNF443 | c.316A>G p.S106G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100042054; called by muse, mutect2, varscan2
- ZNF492 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV101513974, COSV71762191; called by muse, mutect2
- ZNF492 | c.1198A>G p.K400E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101513975; called by muse, mutect2, varscan2
- ZNF530 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100252480; called by muse, mutect2, varscan2
- ZNF536 | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100834992; called by muse, mutect2, varscan2
- ZNF681 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.122); catalogued as COSV101267432; called by muse, mutect2, varscan2
- ZNF777 | c.1647G>A p.M549I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV99925091; called by muse, mutect2, varscan2
- ZNF804A | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.203); catalogued as COSV100167276; called by muse, mutect2
- ZNF836 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100440798; called by muse, mutect2, varscan2
- AMY1C | c.1076G>T p.W359L | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CNPY4 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC19 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- IGHV1-45 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ILDR2 | c.277dup p.C93Lfs*35 | Frame Shift Ins (INS) | VAF 21/147 reads (14%) | called by mutect2, pindel, varscan2
- MVB12A | c.471del p.K158Sfs*85 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- OR2F1 | c.677del p.L226Qfs*56 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- OR56A3 | c.711dup p.V238Rfs*32 | Frame Shift Ins (INS) | VAF 60/223 reads (27%) | called by mutect2, pindel, varscan2
- PLGLB2 | c.251T>C p.I84T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); called by mutect2, varscan2
- SERINC5 | c.1161_1177del p.Y388Pfs*? | Frame Shift Del (DEL) | VAF 39/154 reads (25%) | called by mutect2, pindel, varscan2
- SPIDR | c.213del p.I72Lfs*28 | Frame Shift Del (DEL) | VAF 40/218 reads (18%) | called by mutect2, pindel, varscan2
- SVEP1 | c.6408del p.M2137Cfs*17 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- TRAV30 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- A4GNT | c.933C>T p.L311= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV99367780; called by muse, mutect2, varscan2
- ABCC10 | c.3319C>T p.L1107= (on ENST00000372530 / NM_001198934.2; = p.L1079= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99767032; called by muse, mutect2, varscan2
- ABCC5 | c.1662C>T p.D554= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as rs772552244, COSV55597616; called by muse, mutect2
- ACSBG1 | c.2028C>A p.P676= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99357241; called by muse, mutect2, varscan2
- AHDC1 | c.3678G>A p.Q1226= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99899127; called by muse, mutect2, varscan2
- ALPK2 | c.5544C>T p.A1848= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100864275; called by muse, mutect2, varscan2
- ALPK3 | c.877C>T p.L293= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99360644; called by muse, mutect2
- ANK2 | c.10044C>A p.L3348= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100000843, COSV52189247; called by muse, mutect2, varscan2
- AP002748.5 | c.1209C>G p.V403= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100567839; called by muse, mutect2, varscan2
- ASAP3 | c.1443C>G p.L481= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100369342; called by muse, mutect2
- ATP2C1 | c.2184T>G p.P728= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100146561; called by muse, mutect2, varscan2
- AWAT1 | c.522C>A p.L174= | Silent (SNP) | VAF 28/299 reads (9%) | catalogued as COSV100997193, COSV65738413; called by muse, mutect2
- BRINP3 | c.2004G>T p.V668= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV100818619; called by muse, mutect2, varscan2
- CCDC92 | c.132G>C p.T44= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs750311683, COSV53019217, COSV99435415; called by muse, varscan2
- CDH12 | c.1845G>A p.G615= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV101202103; called by muse, mutect2
- CDH22 | c.1648C>T p.L550= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100952812; called by muse, mutect2
- CNOT8 | c.225C>T p.I75= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99597158; called by muse, mutect2, varscan2
- COL24A1 | c.969T>G p.S323= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100993132; called by muse, mutect2, varscan2
- DCC | c.3381C>A p.A1127= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101472659; called by muse, mutect2, varscan2
- DNAAF2 | c.462C>T p.A154= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100023918; called by muse, mutect2, varscan2
- DNAH7 | c.9399G>A p.L3133= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100414638; called by muse, mutect2, varscan2
- DNM2 | c.69C>T p.I23= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1213386129, COSV99139036; called by muse, mutect2, varscan2
- DOCK6 | c.5109G>A p.V1703= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99625258; called by muse, mutect2, varscan2
- DRC7 | c.1083G>A p.L361= | Silent (SNP) | VAF 8/199 reads (4%) | catalogued as COSV100395486; called by muse, mutect2
- ELAC2 | c.2046C>G p.L682= | Silent (SNP) | VAF 40/243 reads (16%) | catalogued as COSV99310464; called by muse, mutect2, varscan2
- ELFN2 | c.1014C>T p.T338= | Silent (SNP) | VAF 18/298 reads (6%) | catalogued as COSV101297521; called by muse, mutect2
- EPC1 | c.2373G>A p.L791= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as COSV99552792; called by muse, mutect2, varscan2
- EPHB6 | c.2976G>A p.L992= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as COSV100844233; called by muse, mutect2, varscan2
- F13A1 | c.1653A>G p.T551= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV99342681; called by muse, mutect2, varscan2
- FOXM1 | c.969G>A p.V323= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100700825; called by muse, mutect2, varscan2
- FSTL3 | c.663G>A p.S221= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs377720232, COSV99383844; called by muse, mutect2, varscan2
- GBP3 | c.199C>T p.L67= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs752566632, COSV99352433; called by muse, mutect2, varscan2
- GPR63 | c.1207C>A p.R403= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100013248, COSV100013486; called by muse, mutect2, varscan2
- GUCY2C | c.2472A>G p.T824= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99663480; called by muse, mutect2, varscan2
- H2AW | c.351G>A p.L117= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100797267; called by muse, mutect2, varscan2
- H3C13 | c.255C>T p.F85= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV100516069; called by muse, mutect2
- HDLBP | c.2226C>G p.L742= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100190287; called by muse, varscan2
- HECW2 | c.2763C>G p.P921= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as rs781631738, COSV99646682; called by muse, mutect2, varscan2
- HOXA13 | c.858C>T p.N286= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs375188427, COSV56083894; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.93A>T p.V31= | Silent (SNP) | VAF 133/340 reads (39%) | called by muse, mutect2, varscan2
- IGHV6-1 | c.129C>A p.A43= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- IGLC7 | c.291G>A p.E97= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- INSRR | c.2970T>C p.F990= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100947344; called by muse, mutect2, varscan2
- KLHDC4 | c.1506C>G p.G502= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV54507283, COSV99566263; called by muse, mutect2, varscan2
- KNTC1 | c.1824G>C p.V608= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV100338162; called by muse, mutect2, varscan2
- KRT25 | c.753G>A p.L251= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100379877; called by muse, mutect2, varscan2
- KRTAP27-1 | c.216C>T p.D72= | Silent (SNP) | VAF 29/190 reads (15%) | catalogued as rs376929358, COSV101239699; called by muse, mutect2, varscan2
- LALBA | c.428G>A p.*143= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99974376; called by muse, mutect2, varscan2
- MAMDC2 | c.1083C>A p.T361= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs771986746, COSV101015403; called by muse, mutect2, varscan2
- MARCHF11 | c.987C>T p.D329= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs764612045, COSV100197701; called by muse, mutect2, varscan2
- MCM2 | c.1869C>T p.R623= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99413006; called by muse, mutect2
- MED12 | c.322C>A p.R108= | Silent (SNP) | VAF 47/82 reads (57%) | catalogued as COSV100377193; called by muse, mutect2, varscan2
- MGAM | c.1083A>G p.Q361= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as COSV101527439; called by muse, mutect2, varscan2
- MRPL45 | c.273T>A p.P91= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- MUS81 | c.1131C>G p.L377= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100337216; called by muse, mutect2, varscan2
- MYH10 | c.3771C>T p.L1257= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs780658326, COSV99344798; called by muse, mutect2, varscan2
- NAT8 | c.306G>C p.L102= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV99721970; called by muse, mutect2, varscan2
- NAV2 | c.2829C>T p.D943= (on ENST00000396087 / NM_001244963.2; = p.D920= on NM_145117.5) | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs143699420; called by muse, mutect2, varscan2
- NDRG2 | c.852G>A p.S284= (on ENST00000298687 / NM_001354570.1; = p.S270= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs755842783, COSV100068951, COSV53872948; called by muse, mutect2, varscan2
- NDST2 | c.432C>G p.L144= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV55215582, COSV55217825; called by muse, mutect2, varscan2
- NF1 | c.2983C>T p.L995= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV100646606; called by muse, mutect2, varscan2
- NR0B1 | c.240C>G p.L80= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV66763994, COSV66764157; called by muse, mutect2, varscan2
- NR4A1 | c.774G>T p.G258= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as rs746689109, COSV99671183; called by muse, mutect2, varscan2
- OLFM4 | c.1407T>A p.I469= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1566321607, COSV99524266; called by muse, mutect2, varscan2
- OPN4 | c.975C>T p.H325= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs199918331, COSV54119228, COSV99618209; called by muse, mutect2, varscan2
- OR10H2 | c.630C>G p.G210= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV100008714; called by muse, mutect2, varscan2
- OR1E2 | c.534T>C p.C178= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99943417; called by muse, mutect2, varscan2
- OR2M3 | c.516G>T p.R172= | Silent (SNP) | VAF 46/196 reads (23%) | catalogued as COSV101513416, COSV71759372; called by muse, mutect2, varscan2
- OR52H1 | c.447C>T p.G149= (on ENST00000322653; = p.G155= on NM_001005289.1) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs931568596, COSV100497295; called by muse, mutect2, varscan2
- OR6C65 | c.687C>T p.A229= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV101110179; called by muse, mutect2, varscan2
- OSM | c.6G>T p.G2= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV99304104; called by muse, mutect2, varscan2
- PAPPA2 | c.3231G>C p.T1077= | Silent (SNP) | VAF 61/261 reads (23%) | catalogued as COSV62792179, COSV62811799; called by muse, mutect2, varscan2
- PAXBP1 | c.1743C>T p.S581= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs140333561; called by muse, mutect2, varscan2
- PCDH11X | c.4017C>A p.S1339= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV53445084; called by muse, mutect2, varscan2
- PCDHB5 | c.1614G>T p.P538= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV50657271, COSV99167804; called by muse, mutect2, varscan2
- PCLO | c.12651A>C p.S4217= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100430322; called by muse, mutect2, varscan2
- PGAP1 | c.18T>G p.V6= | Silent (SNP) | VAF 22/225 reads (10%) | catalogued as COSV100698117; called by muse, mutect2
- PIK3CG | c.678C>G p.R226= | Silent (SNP) | VAF 30/229 reads (13%) | catalogued as COSV100782772; called by muse, mutect2, varscan2
- PLEKHA1 | c.1074C>G p.V358= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100935467; called by muse, mutect2, varscan2
- PRICKLE3 | c.507G>T p.L169= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100889906; called by muse, mutect2, varscan2
- PRPF3 | c.480G>C p.L160= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1353235876, COSV100254689; called by muse, mutect2
- PRRG3 | c.276G>C p.L92= | Silent (SNP) | VAF 67/229 reads (29%) | catalogued as COSV100948588; called by muse, mutect2, varscan2
- PTGER4 | c.459G>T p.L153= | Silent (SNP) | VAF 48/153 reads (31%) | catalogued as COSV100201502; called by muse, mutect2, varscan2
- RAB5C | c.237A>T p.G79= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs1420834435, COSV100651398; called by muse, mutect2, varscan2
- RAET1G | c.282G>C p.L94= | Silent (SNP) | VAF 62/269 reads (23%) | catalogued as COSV100951655, COSV66275194; called by muse, mutect2, varscan2
- RASGRF1 | c.2172C>T p.Y724= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs770172047, COSV101174436; ClinVar: likely benign; called by muse, mutect2, varscan2
- REXO5 | c.1563G>A p.L521= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs1158962182, COSV99759085; called by muse, mutect2, varscan2
- RP1 | c.5322C>A p.T1774= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99606985; called by muse, mutect2, varscan2
- SCARA3 | c.1077C>A p.T359= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as COSV100106649; called by muse, mutect2, varscan2
- SLC12A3 | c.1791C>G p.L597= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99344026; called by muse, mutect2
- SLC6A11 | c.456A>T p.A152= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV99594344; called by muse, mutect2, varscan2
- SLC7A3 | c.840C>A p.P280= | Silent (SNP) | VAF 70/115 reads (61%) | catalogued as COSV99979482; called by muse, mutect2, varscan2
- SMIM8 | c.174A>T p.S58= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99994709; called by muse, mutect2, varscan2
- STK35 | c.1422C>G p.V474= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99852702; called by muse, mutect2, varscan2
- TAS2R31 | c.357T>G p.L119= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV101114579; called by muse, mutect2
- TBX10 | c.513C>G p.L171= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as COSV100039684; called by muse, mutect2, varscan2
- TEX10 | c.1462A>C p.R488= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100887680; called by muse, mutect2, varscan2
- TMED3 | c.81C>G p.A27= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100229942; called by muse, mutect2
- TMEM200C | c.1621C>A p.R541= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1280267248, COSV101274809, COSV67309191; called by muse, mutect2, varscan2
- TNIP2 | c.774G>A p.R258= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100198637; called by muse, mutect2, varscan2
- TPR | c.1989A>G p.T663= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV100823793; called by muse, mutect2, varscan2
- TRPS1 | c.2529T>C p.Y843= (on ENST00000220888 / NM_001330599.2; = p.Y856= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99629733; called by muse, mutect2
- TTN | c.16755G>C p.G5585= (on ENST00000591111; = p.G4658= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/346 reads (18%) | catalogued as COSV100604316; called by muse, mutect2, varscan2
- UPB1 | c.24G>A p.S8= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs1172141022, COSV100387140, COSV58115011; called by muse, mutect2, varscan2
- USH2A | c.11124C>A p.P3708= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100232572; called by muse, mutect2, varscan2
- USP36 | c.3318C>T p.N1106= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV100361393; called by muse, mutect2, varscan2
- UTRN | c.2091A>G p.A697= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100839782; called by muse, mutect2, varscan2
- VN1R4 | c.717G>A p.V239= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100237388; called by muse, mutect2, varscan2
- WDR17 | c.3783G>A p.V1261= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1358349674, COSV99707310; called by muse, mutect2, varscan2
- XKRX | c.765C>T p.L255= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV100139634; called by muse, mutect2, varscan2
- ZNF331 | c.549G>T p.G183= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV53476025, COSV99467131; called by muse, mutect2, varscan2
- ZNF556 | c.699T>C p.C233= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100298678; called by muse, mutect2, varscan2
- ZNF665 | c.1590A>G p.E530= (on ENST00000600412; = p.E595= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV101128195; called by muse, mutect2, varscan2
- AL590867.2 | n.154T>C | RNA (SNP) | VAF 35/235 reads (15%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847186 A>T | 5'Flank (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
- MAGEC3 | c.1729-55C>T | Intron (SNP) | VAF 24/112 reads (21%) | catalogued as rs891995647, COSV100025175; called by muse, mutect2, varscan2
- NEBL | c.164+25925A>G | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as COSV101008760; called by muse, mutect2, varscan2
- OR3A4P | n.658T>A | RNA (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253033 G>T | 5'Flank (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99310266; called by muse, mutect2
- RNF213 | c.3024+142G>T | Intron (SNP) | VAF 30/110 reads (27%) | catalogued as COSV100173337, COSV100174021; called by muse, mutect2, varscan2
- SNORD115-15 | n.67A>G | RNA (SNP) | VAF 68/314 reads (22%) | called by muse, mutect2, varscan2
- SSX7 | c.-2C>G | 5'UTR (SNP) | VAF 79/270 reads (29%) | catalogued as COSV99993792; called by muse, mutect2, varscan2
